Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7747, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7747-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Right and left pelvic lymph nodes, regional resection:

Four lymph nodes negative for metastatic tumor (0/4).

B. Prostate, radical prostatectomy:

Infiltrating prostatic adenocarcinoma.

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Prostate size: 4.5 x 3.0 x 2.8 cm.
3. Tumor quantitation: Tumor involves approximately 25% of the gland.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 7/10.
5. Extraprostatic extension: Not identified.
6. Seminal vesicle involvement: Tumor closely abuts the junction between the prostate and the seminal vesicles, but there is no evidence of involvement of the seminal vesicles proper.
7. Perineural invasion: Present.
8. High grade PIN: Present.

Surgical Margin Status:

1. Multiple inked surgical margins of resection are positive for tumor, including the apex, right anterior, and right posterior.

Lymph Node Status: Four lymph nodes negative for tumor - see part A above.

Other:

1. pTNM stage: T2cN0M0 IIB.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Right and left pelvic lymph node.

B. Prostate.

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in two formalin filled containers labeled with the patients name

A. Container A is additionally labeled 'right and left pelvic nodes' and contains a 6.0 x 4.0 x 2.0 cm aggregate of yellow-tan fibrofatty soft tissue. On palpation four firm fatty possible lymph nodes are identified ranging from 1.5 up to 3.5 cm in greatest dimension. They are entirely submitted in cassettes A1-3 labeled designated as follows: 1 -- two whole possible lymph nodes; 2 & 3 -- one whole possible bisected lymph node in each cassette.

B. Container B is additionally labeled 'prostate' and contains a 23.9 gram, 4.5 x 3.0 x 2.8 cm prostate received with attached bilateral adnexa which has overall dimensions of 4.0 x 2.2 x 1.0 cm. The capsule is pink-tan and shaggy. Specimen is inked as follows: red side blue and left side black. The base and apical margins are coned and serially sectioned. The remainder of the gland is serially sectioned from apex to base to reveal a pink-tan focally cystic cut surface with periurethral nodularity. No calculi or masses are identified. Representative sections are submitted in B1-18 labeled designated as follows: 1 -- right prostate/seminal vesicle junction; 2 -- left prostate/ seminal vesicle junction; 3 & 4 -- apical margin.

[page 2 of 2]
perpendicular; 5 & 6 -- base margin, perpendicular; 7-9 -- right anterior, apex to base; 10-12 -- right posterior apex to base; 13-15 -- left anterior, apex to base; 16-18 -- left posterior, apex to base. Additionally, a yellow and green cassette are submitted for Genomics research each labeled [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file be40498e-b758-402e-8523-ccfa64101bea (TCGA-HC-7747.CD814697-95E2-46D6-8F80-4467D7BEDF01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).